Somatic mutation profile of tumor specimen C3N-01196-04 (aliquot CPT0078580006) from CPTAC case C3N-01196, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.2 years (24,546 days).
Specimen C3N-01196-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ab2415-cd71-4905-8660-34333134e916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01196-31 (Blood Derived Normal), aliquot CPT0078600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9cefda3-5680-4916-b244-fa0a5d38c465

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Intron 3, Frame Shift Del 3, 5'UTR 3, RNA 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 244/315 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1orf194 | c.418C>G p.H140D (on ENST00000369948 / NM_001245025.3; = p.H128D on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV64050298; called by muse, mutect2, varscan2
- CLEC4F | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs149379407; called by muse, mutect2, varscan2
- CNGB1 | c.3128C>T p.T1043M | Missense Mutation (SNP) | VAF 99/373 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200202348; called by muse, mutect2, varscan2
- CNTNAP5 | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as rs766832930, COSV101444319; called by muse, varscan2
- DNAH2 | c.9352C>T p.R3118W | Missense Mutation (SNP) | VAF 120/152 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746986584, COSV101209688; called by muse, mutect2, varscan2
- DPYSL5 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99982459; called by muse, mutect2, varscan2
- FETUB | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149523201, COSV54004743; called by muse, mutect2, varscan2
- FMNL3 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs377232039; called by muse, mutect2, varscan2
- IBSP | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs577019057, COSV56895334; called by muse, mutect2
- IGHM | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 451/992 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as rs540744199; called by muse, mutect2, varscan2
- IGHMBP2 | c.2912G>A p.R971K | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1471799706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGKV2D-26 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs552537618; called by muse, mutect2, varscan2
- KCNA4 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 172/391 reads (44%) | catalogued as COSV60255201; called by muse, mutect2, varscan2
- KPNA7 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs1475158567; called by muse, mutect2, varscan2
- MYOM2 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 202/565 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs370995476; called by muse, mutect2, varscan2
- NR4A1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 177/424 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.214); catalogued as rs761942358; called by muse, mutect2, varscan2
- OR8G5 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 121/272 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100422183; called by muse, mutect2, varscan2
- PCDHA11 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56536351; called by muse, mutect2, varscan2
- PDE1B | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs558733078, COSV54492626; called by muse, mutect2, varscan2
- PLEKHG4 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs760420600; called by muse, mutect2, varscan2
- PSG3 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 174/445 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs188987120, COSV59503147; called by muse, mutect2, varscan2
- SLC45A2 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV56877223; called by muse, mutect2, varscan2
- SLC5A7 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998009546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYMPK | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 127/359 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs752160318; called by muse, mutect2, varscan2
- TENT5C | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.984); catalogued as rs538766512, COSV65616490; called by muse, mutect2, varscan2
- TNFRSF1B | c.823A>C p.I275L | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1298260090; called by muse, mutect2, varscan2
- TUBA3C | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs201563264, COSV67139779; called by muse, mutect2, varscan2
- ZC3H7B | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 177/214 reads (83%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs779832096, COSV60961129; called by muse, mutect2, varscan2
- AKAP6 | c.264del p.Y89Ifs*16 | Frame Shift Del (DEL) | VAF 111/286 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD33 | c.512C>T p.A171V (on ENST00000340970 / NM_001304459.2; = p.A296V on NM_182608.4) | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL17A1 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DACT2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK10 | c.4040C>A p.T1347K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- EEF1A1 | c.442_445del p.I149Sfs*39 | Frame Shift Del (DEL) | VAF 29/149 reads (19%) | called by mutect2, pindel, varscan2
- H2BW2 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ISL2 | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISLR2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF26A | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSL3 | c.737del p.P246Qfs*16 (on ENST00000312196 / NM_078629.4; = p.P80Qfs*16 on NM_006800.4) | Frame Shift Del (DEL) | VAF 34/55 reads (62%) | called by mutect2, pindel
- MUC17 | c.12772A>C p.T4258P | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCR3LG1 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 105/212 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PKHD1L1 | c.8491A>G p.I2831V | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R12A | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RRN3 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- SEMA3A | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCIN1 | c.1087C>T p.R363C (on ENST00000621492; = p.R329C on NM_025248.3) | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNPO3 | c.2359G>T p.D787Y | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ENKD1 | c.513C>T p.C171= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs749775704; called by muse, mutect2, varscan2
- KCNH1 | c.2388G>A p.T796= (on ENST00000271751 / NM_172362.3; = p.T769= on NM_002238.4) | Silent (SNP) | VAF 77/181 reads (43%) | catalogued as rs138875472; called by muse, mutect2, varscan2
- KEL | c.48G>A p.Q16= | Silent (SNP) | VAF 229/897 reads (26%) | called by muse, mutect2, varscan2
- MLXIPL | c.2082G>A p.Q694= | Silent (SNP) | VAF 143/620 reads (23%) | catalogued as COSV100515329, COSV57669485; called by muse, mutect2, varscan2
- MYH13 | c.75C>T p.I25= | Silent (SNP) | VAF 155/217 reads (71%) | catalogued as rs776603506, COSV52821522; called by muse, mutect2, varscan2
- NOTCH4 | c.2946C>T p.T982= | Silent (SNP) | VAF 104/295 reads (35%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1458C>T p.N486= | Silent (SNP) | VAF 401/1025 reads (39%) | catalogued as rs1423575450, COSV65356535; called by muse, mutect2, varscan2
- RARG | c.1092C>T p.Y364= | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as rs769206913; called by muse, mutect2, varscan2
- RECQL4 | c.756C>T p.P252= | Silent (SNP) | VAF 138/310 reads (45%) | catalogued as rs1217355588; called by muse, mutect2, varscan2
- TTC39B | c.1128G>A p.A376= | Silent (SNP) | VAF 27/264 reads (10%) | catalogued as rs376726304; called by muse, mutect2, varscan2
- ZNF283 | c.1227G>A p.G409= | Silent (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- ABI3BP | c.80-19187_80-19186insTAA | Intron (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel
- AC004947.2 | n.29C>T | RNA (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- CYP3A7 | c.165+26T>C | Intron (SNP) | VAF 32/114 reads (28%) | catalogued as rs1255042324; called by muse, varscan2
- LMX1B | c.*13C>T | 3'UTR (SNP) | VAF 139/314 reads (44%) | catalogued as rs375458623, COSV100827144; called by muse, mutect2, varscan2
- MC2R | c.-49G>A | 5'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as rs200249547; called by muse, mutect2, varscan2
- SLC25A21 | c.-194C>T | 5'UTR (SNP) | VAF 14/484 reads (3%) | called by muse, mutect2
- TH | c.-19C>T | 5'UTR (SNP) | VAF 91/215 reads (42%) | catalogued as rs779891694; called by muse, mutect2, varscan2
- ZNF836 | c.142+30A>C | Intron (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
